Somatic mutation profile of tumor specimen ALCH-B04H-TTP1-A (aliquot ALCH-B04H-TTP1-A-1-0-D-A679-36) from ALCHEMIST case ALCH-B04H, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 73.9 years (26,983 days).
Specimen ALCH-B04H-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa02d9df-e0aa-4aa3-b6b2-dbb276759280.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B04H-NB1-A (Blood Derived Normal), aliquot ALCH-B04H-NB1-A-1-0-D-A679-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/537da480-43f1-4329-90fd-6e88059bc890

The open-access MAF lists 311 somatic variants for this specimen: 196 protein-altering or splice-affecting, 68 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 68, Intron 26, Nonsense Mutation 16, RNA 10, Frame Shift Del 8, 5'UTR 6, Splice Site 5, Frame Shift Ins 3, 5'Flank 2, Splice Region 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2A | c.2318dup p.S774Vfs*12 | Frame Shift Ins (INS) | VAF 102/238 reads (43%) | catalogued as rs782297546; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.783-1G>T p.X261_splice | Splice Site (SNP) | VAF 68/260 reads (26%) | hotspot (GDC flag); catalogued as rs1555525367, CS137625, COSV52668714, COSV52729930, COSV53769335; ClinVar: likely pathogenic / not provided; called by muse, varscan2
- AKAP1 | c.2047A>G p.I683V | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as rs754908201; called by muse, mutect2, varscan2
- ATP10A | c.3789G>T p.W1263C | Missense Mutation (SNP) | VAF 82/254 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100791064, COSV63520914; called by muse, varscan2
- CCER1 | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62648936; called by muse, mutect2, varscan2
- CDH10 | c.742G>T p.G248C | Missense Mutation (SNP) | VAF 68/303 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52589426; called by muse, mutect2, varscan2
- CDH20 | c.1132A>T p.I378F | Missense Mutation (SNP) | VAF 124/473 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV53007605; called by muse, mutect2, varscan2
- CDKN2A | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 24/53 reads (45%) | catalogued as CM072932, COSV58701530, COSV58721492; called by muse, mutect2, varscan2
- CDX2 | c.916dup p.V306Gfs*31 | Frame Shift Ins (INS) | VAF 11/25 reads (44%) | catalogued as rs773511514; called by mutect2, varscan2
- CEP152 | c.3071G>A p.R1024H | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs199914670; ClinVar: uncertain significance; called by mutect2, varscan2
- COL11A1 | c.3455C>A p.P1152Q | Missense Mutation (SNP) | VAF 51/249 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.276); catalogued as COSV62194966; called by muse, mutect2, varscan2
- CREB3L3 | c.514C>A p.L172M | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV50178496; called by muse, mutect2, varscan2
- DDX54 | c.2339G>A p.R780H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs766588291; called by muse, mutect2, varscan2
- DISP3 | c.1187G>T p.R396L | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780545984, COSV99610417; called by muse, mutect2, varscan2
- DPP6 | c.2258C>A p.S753Y (on ENST00000377770 / NM_001364500.2; = p.S691Y on NM_001936.5) | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59597680; called by muse, mutect2, varscan2
- DPPA4 | c.727G>T p.D243Y | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV59512669; called by muse, mutect2, varscan2
- ERN2 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as rs371169798; called by muse, mutect2, varscan2
- FCRL3 | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 77/331 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as rs148789146, COSV100943549; called by muse, mutect2, varscan2
- GALNT17 | c.1477C>G p.P493A | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.932); catalogued as rs1358171981, COSV61149156; called by muse, mutect2, varscan2
- GAS2L3 | c.817T>C p.F273L | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs1293527082; called by muse, mutect2, varscan2
- GLB1L2 | c.1354C>T p.Q452* | Nonsense Mutation (SNP) | VAF 19/77 reads (25%) | catalogued as COSV60277982, COSV60278404; called by muse, mutect2
- GRIA4 | c.1193T>G p.L398W | Missense Mutation (SNP) | VAF 87/317 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.57); catalogued as COSV56913461; called by muse, mutect2, varscan2
- GRIN2A | c.3501G>T p.M1167I | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV58019009; called by muse, mutect2, varscan2
- HFM1 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99646490; called by muse, mutect2, varscan2
- HMCN2 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.911); catalogued as rs1179110042; called by muse, mutect2
- IRS1 | c.583G>T p.V195L | Missense Mutation (SNP) | VAF 108/344 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV59337161; called by muse, mutect2, varscan2
- KCNB1 | c.1550C>A p.S517* | Nonsense Mutation (SNP) | VAF 31/157 reads (20%) | catalogued as COSV65566515; called by muse, mutect2, varscan2
- LMOD2 | c.1487T>C p.I496T | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs780342449; called by muse, mutect2, varscan2
- MAGEC1 | c.587C>A p.S196Y | Missense Mutation (SNP) | VAF 79/239 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as COSV53570983; called by muse, mutect2, varscan2
- MBD1 | c.1124del p.R375Pfs*8 (on ENST00000269468 / NM_001323950.1; = p.R352Pfs*8 on NM_015845.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 75/262 reads (29%) | catalogued as COSV53998612; called by mutect2, pindel, varscan2
- MMP26 | c.274A>T p.I92F | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV56172769; called by muse, mutect2, varscan2
- NAALAD2 | c.1984G>T p.E662* | Nonsense Mutation (SNP) | VAF 70/212 reads (33%) | catalogued as COSV100428137; called by muse, mutect2, varscan2
- NBEA | c.8455G>A p.G2819R | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV59827052; called by muse, mutect2, varscan2
- NCAM2 | c.1921G>C p.E641Q | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as rs1245328253; called by muse, mutect2
- NDUFC2 | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55248967; called by muse, mutect2, varscan2
- NID1 | c.455C>G p.A152G | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV51615363; called by muse, mutect2, varscan2
- NUAK1 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.277); catalogued as COSV54602934; called by muse, mutect2, varscan2
- OR52E8 | c.296C>G p.S99C | Missense Mutation (SNP) | VAF 80/257 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV66204679; called by muse, mutect2, varscan2
- OR5J2 | c.344T>A p.L115Q | Missense Mutation (SNP) | VAF 100/291 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs553805754; called by muse, mutect2, varscan2
- OTOP1 | c.725C>T p.T242I | Missense Mutation (SNP) | VAF 115/363 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV56395898; called by muse, mutect2, varscan2
- PCDHB11 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV53378388, COSV99504842; called by muse, mutect2, varscan2
- PCDHB12 | c.1597G>T p.A533S | Missense Mutation (SNP) | VAF 74/174 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53395652; called by muse, varscan2
- PNLIPRP2 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100077759, COSV53943045; called by muse, mutect2, varscan2
- PPP3R2 | c.23C>A p.P8Q | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV62451814; called by muse, mutect2, varscan2
- PRDM9 | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 113/445 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57012787; called by muse, mutect2, varscan2
- PRDM9 | c.2478C>A p.H826Q | Missense Mutation (SNP) | VAF 118/325 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57007476, COSV99689938; called by muse, mutect2, varscan2
- PSMB9 | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.208); catalogued as rs769219403; called by muse, mutect2, varscan2
- PUS10 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 57/327 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as COSV100369430; called by muse, mutect2, varscan2
- RAB17 | c.191C>G p.A64G | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99221310; called by muse, mutect2, varscan2
- RAB43 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59348711; called by muse, mutect2
- RGS5 | c.470G>T p.R157I | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs770595330, COSV100008902, COSV58352409; called by muse, mutect2, varscan2
- RNF20 | c.425G>T p.R142L | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV66355596; called by muse, mutect2, varscan2
- RYR2 | c.1612G>A p.A538T | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100772057; called by muse, mutect2, varscan2
- SCG2 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746725984, COSV100544669; called by muse, mutect2, varscan2
- SCYL2 | c.2683G>C p.G895R | Missense Mutation (SNP) | VAF 106/390 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV62568949; called by muse, mutect2, varscan2
- SIGLEC12 | c.1718C>T p.A573V (on ENST00000291707 / NM_053003.4; = p.A455V on NM_033329.2) | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs760382655, COSV52465653; called by muse, mutect2, varscan2
- SLITRK2 | c.1524C>A p.H508Q | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.295); catalogued as COSV59427062; called by muse, mutect2, varscan2
- SPOPL | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 18/153 reads (12%) | catalogued as rs564888975; called by muse, mutect2, varscan2
- TBC1D10C | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); catalogued as rs760305095; called by muse, mutect2, varscan2
- TMEM79 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as COSV55293040; called by mutect2, varscan2
- TRERF1 | c.2773G>T p.V925L | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV61667725; called by muse, mutect2
- TTN | c.17704G>A p.E5902K (on ENST00000591111; = p.E4975K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/143 reads (38%) | PolyPhen benign (0.439); catalogued as rs72648948; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.17642C>A p.P5881H (on ENST00000591111; = p.P4954H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | PolyPhen possibly damaging (0.77); catalogued as COSV100620334; called by muse, mutect2, varscan2
- TUBB2B | c.166+1G>A p.X56_splice | Splice Site (SNP) | VAF 37/196 reads (19%) | catalogued as COSV99455596; called by muse, mutect2, varscan2
- URB2 | c.4500C>G p.I1500M | Missense Mutation (SNP) | VAF 69/239 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV51019763; called by muse, mutect2, varscan2
- USP17L7 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 58/506 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs183320421; called by muse, varscan2
- VCAN | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 233/590 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54102348; called by muse, mutect2, varscan2
- WDR81 | c.3379G>A p.E1127K (on ENST00000409644 / NM_001163809.2; = p.E76K on NM_152348.4) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as rs756632634, COSV58480968; called by muse, mutect2, varscan2
- XIRP2 | c.307A>T p.S103C | Missense Mutation (SNP) | VAF 69/315 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.639); catalogued as rs188658609; called by muse, mutect2, varscan2
- ZNF385D | c.1144C>A p.P382T | Missense Mutation (SNP) | VAF 103/204 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99873752; called by muse, mutect2, varscan2
- ZNF536 | c.3073C>A p.L1025M | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV62819765; called by muse, mutect2, varscan2
- ZNF7 | c.1624A>G p.I542V | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as rs368962858; called by muse, mutect2, varscan2
- ZNF804A | c.1717C>A p.L573I | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs767954726; called by muse, mutect2, varscan2
- ZNF808 | c.1520G>T p.G507V | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63121447; called by muse, mutect2, varscan2
- ADGRF1 | c.2344G>T p.D782Y | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ANKRD33B | c.1225del p.L409Cfs*167 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- ANKRD66 | c.26G>T p.R9M | Missense Mutation (SNP) | VAF 78/217 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- ANOS1 | c.1608C>G p.C536W | Missense Mutation (SNP) | VAF 74/134 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ASPDH | c.150C>A p.S50R | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- BRCC3 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 78/150 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, varscan2
- BRINP1 | c.47del p.G16Afs*65 | Frame Shift Del (DEL) | VAF 44/230 reads (19%) | called by mutect2, pindel, varscan2
- CAGE1 | c.1733C>T p.S578L (on ENST00000512086; = p.S442L on NM_205864.3) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- CAPS2 | c.289A>T p.T97S | Missense Mutation (SNP) | VAF 68/354 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CARF | c.719A>G p.Q240R | Missense Mutation (SNP) | VAF 77/286 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CASD1 | c.354T>C p.H118= | Splice Region (SNP) | VAF 41/146 reads (28%) | called by muse, mutect2, varscan2
- CASD1 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 41/147 reads (28%) | called by muse, mutect2, varscan2
- CCDC154 | c.524G>A p.R175K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC185 | c.824_825dup p.L276Sfs*13 | Frame Shift Ins (INS) | VAF 39/150 reads (26%) | called by mutect2, pindel, varscan2
- CDHR4 | c.1841C>A p.P614Q | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- CNKSR2 | c.2018A>C p.E673A | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- CNTN3 | c.1732A>T p.M578L | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CNTNAP5 | c.1262A>T p.E421V | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CNTNAP5 | c.1666G>T p.E556* | Nonsense Mutation (SNP) | VAF 78/220 reads (35%) | called by muse, varscan2
- CPNE8 | c.708G>T p.W236C | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DCDC2B | c.997C>A p.Q333K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DCHS1 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DDHD1 | c.1611C>A p.H537Q (on ENST00000323669; = p.H734Q on NM_030637.3) | Missense Mutation (SNP) | VAF 123/272 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- DMD | c.7806del p.K2602Nfs*12 | Frame Shift Del (DEL) | VAF 120/220 reads (55%) | called by mutect2, pindel*, varscan2
- ECI1 | c.11T>A p.V4E | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EFCAB7 | c.997G>T p.E333* | Nonsense Mutation (SNP) | VAF 26/101 reads (26%) | called by muse, mutect2, varscan2
- ERCC6L2 | c.2714G>C p.C905S | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ERICH6B | c.256C>G p.L86V | Missense Mutation (SNP) | VAF 105/232 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- EYS | c.2437T>A p.C813S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.314); called by muse, varscan2
- FAM209A | c.359A>T p.E120V | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT1 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GATAD2A | c.289A>G p.R97G | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); called by muse, mutect2
- GLRA3 | c.688T>A p.Y230N | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GLTPD2 | c.267C>A p.F89L | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GOLGA8M | c.423G>C p.Q141H | Missense Mutation (SNP) | VAF 173/564 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- HDAC4 | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 35/154 reads (23%) | called by muse, mutect2, varscan2
- HMGXB4 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 59/295 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- HOXA4 | c.149C>A p.T50N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.027); called by muse, varscan2
- HSD11B1 | c.640G>C p.V214L | Missense Mutation (SNP) | VAF 132/686 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, varscan2
- HSPA4L | c.176A>G p.N59S | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IGKV1D-16 | c.342T>G p.N114K | Missense Mutation (SNP) | VAF 16/293 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- IL2 | c.256C>A p.L86M | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPR1 | c.1800C>A p.H600Q (on ENST00000354582; = p.H585Q on NM_002222.7) | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT28 | c.1366G>T p.G456C | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- LPIN3 | c.980A>G p.E327G | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- LRRC7 | c.882G>T p.E294D (on ENST00000651989 / NM_001370785.2; = p.E261D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MAGEL2 | c.3301G>C p.V1101L | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MED27 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 83/209 reads (40%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- MIA3 | c.3934G>T p.E1312* | Nonsense Mutation (SNP) | VAF 114/345 reads (33%) | called by muse, mutect2, varscan2
- MORC1 | c.2416C>G p.P806A | Missense Mutation (SNP) | VAF 94/360 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MRTFA | c.2893G>A p.E965K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- MSX1 | c.260A>T p.Q87L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC19 | c.209C>G p.P70R | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- MYT1L | c.3011C>A p.S1004Y | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NAALAD2 | c.1985A>T p.E662V | Missense Mutation (SNP) | VAF 70/213 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDUFB8 | c.554A>T p.E185V | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- NRXN1 | c.2990C>A p.T997N | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NUP107 | c.2048C>G p.A683G | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.301); called by muse, varscan2
- NUP160 | c.4210C>G p.H1404D | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- OR2T34 | c.474G>T p.M158I | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR2Z1 | c.791C>A p.A264D | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- OR5H1 | c.121G>C p.G41R | Missense Mutation (SNP) | VAF 35/345 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ORAI3 | c.514del p.V172Sfs*111 | Frame Shift Del (DEL) | VAF 45/183 reads (25%) | called by mutect2, pindel, varscan2
- PCNX1 | c.3100del p.V1034Sfs*8 | Frame Shift Del (DEL) | VAF 95/248 reads (38%) | called by mutect2, pindel, varscan2
- PCNX3 | c.692G>T p.S231I | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- PER3 | c.1038C>A p.N346K | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PI4K2A | c.55A>C p.T19P | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PIK3C2G | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 50/168 reads (30%) | called by muse, mutect2, varscan2
- PPP6R2 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PRDM2 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PTMS | c.239A>G p.K80R | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); called by muse, varscan2
- R3HDM1 | c.2777G>T p.G926V | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAD54L2 | c.2482G>T p.A828S | Missense Mutation (SNP) | VAF 140/253 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBFA | c.607G>T p.G203* | Nonsense Mutation (SNP) | VAF 95/335 reads (28%) | called by muse, mutect2, varscan2
- RCOR2 | c.135G>C p.M45I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- RGS17 | c.53C>G p.A18G | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RNASET2 | c.537del p.I182Sfs*18 | Frame Shift Del (DEL) | VAF 119/366 reads (33%) | called by mutect2, pindel, varscan2
- RP1 | c.3680A>T p.E1227V | Missense Mutation (SNP) | VAF 110/403 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- RRP9 | c.670C>A p.L224I | Missense Mutation (SNP) | VAF 83/162 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SLAIN1 | c.1469T>A p.M490K (on ENST00000466548; = p.M227K on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/263 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- SLC12A6 | c.2620A>C p.K874Q (on ENST00000354181 / NM_001365088.1; = p.K823Q on NM_005135.2) | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SLC18A2 | c.566G>T p.R189M | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- SLC22A3 | c.426C>A p.S142R | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.425); called by mutect2, varscan2
- SLC46A2 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.026); called by muse, mutect2
- SLC4A10 | c.314C>G p.T105S | Missense Mutation (SNP) | VAF 62/292 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SLC52A3 | c.248C>T p.T83I | Missense Mutation (SNP) | VAF 110/266 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SLCO6A1 | c.1550G>T p.C517F | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- SLU7 | c.709G>C p.D237H | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SMARCA2 | c.3451C>T p.H1151Y | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SPRED2 | c.314del p.P105Lfs*11 | Frame Shift Del (DEL) | VAF 70/368 reads (19%) | called by mutect2, pindel, varscan2
- STARD9 | c.5598T>A p.C1866* | Nonsense Mutation (SNP) | VAF 44/121 reads (36%) | called by muse, mutect2, varscan2
- SYNE1 | c.10212G>A p.W3404* (on ENST00000367255 / NM_182961.4; = p.W3411* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 57/304 reads (19%) | called by muse, mutect2, varscan2
- TCEA2 | c.673_675del p.X225_splice | Splice Site (DEL) | VAF 5/24 reads (21%) | called by mutect2, pindel, varscan2
- TCF21 | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- TFR2 | c.615-3C>T | Splice Region (SNP) | VAF 4/15 reads (27%) | called by mutect2, varscan2
- TMEM131 | c.4084G>T p.D1362Y | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- TNFRSF6B | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TRIM51 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 80/280 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- TRIM72 | c.1112G>T p.R371L | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TSPAN11 | c.150C>G p.S50R | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- TTC29 | c.799G>T p.G267* | Nonsense Mutation (SNP) | VAF 37/135 reads (27%) | called by muse, mutect2, varscan2
- TTN | c.98437G>C p.E32813Q (on ENST00000591111; = p.E25389Q on NM_003319.4) | Missense Mutation (SNP) | VAF 120/316 reads (38%) | PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- TTN | c.48755C>A p.P16252H (on ENST00000591111; = p.P8828H on NM_003319.4) | Missense Mutation (SNP) | VAF 67/173 reads (39%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUT7 | c.3119C>G p.T1040S | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- UBOX5 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- USP6 | c.2123C>T p.S708F | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UTP15 | c.399C>A p.D133E | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- UTRN | c.10130G>A p.S3377N | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VAV3 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 56/309 reads (18%) | called by muse, mutect2, varscan2
- VIP | c.392C>A p.T131N | Missense Mutation (SNP) | VAF 75/211 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- WDR17 | c.67del p.X23_splice | Splice Site (DEL) | VAF 29/92 reads (32%) | called by mutect2, pindel, varscan2
- ZFP37 | c.85G>T p.G29W | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZHX3 | c.1061C>A p.A354D | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ZNF267 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF267 | c.873A>T p.R291S | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF324 | c.62C>G p.A21G | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- ZNF34 | c.1498G>C p.E500Q | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF479 | c.1262C>G p.S421C | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, varscan2
- ZNF595 | c.1493A>T p.H498L | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF689 | c.206-1G>T p.X69_splice | Splice Site (SNP) | VAF 19/81 reads (23%) | called by muse, varscan2
- ZNF716 | c.1206T>A p.H402Q | Missense Mutation (SNP) | VAF 88/310 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- ZSCAN20 | c.1739C>A p.T580N | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACSM5 | c.1441C>A p.R481= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as COSV59371010; called by muse, mutect2, varscan2
- ACTL7A | c.1104T>C p.S368= | Silent (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- ADCY6 | c.2121G>C p.L707= | Silent (SNP) | VAF 45/222 reads (20%) | called by muse, mutect2, varscan2
- AMER3 | c.495C>T p.H165= | Silent (SNP) | VAF 52/155 reads (34%) | called by muse, mutect2, varscan2
- AMER3 | c.1866G>A p.S622= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as rs899603206, COSV58465840; called by muse, mutect2, varscan2
- ARHGEF25 | c.504G>A p.L168= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV99678276; called by muse, varscan2
- ARSJ | c.822T>A p.A274= | Silent (SNP) | VAF 70/277 reads (25%) | called by muse, mutect2, varscan2
- ARVCF | c.1270C>T p.L424= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs1249610297; called by muse, mutect2, varscan2
- ATP10A | c.3807G>A p.L1269= | Silent (SNP) | VAF 44/194 reads (23%) | catalogued as COSV63513948, COSV63522707; called by muse, varscan2
- ATP13A5 | c.2175G>A p.T725= | Silent (SNP) | VAF 19/137 reads (14%) | catalogued as rs1227845655, COSV100665705; called by muse, mutect2, varscan2
- B9D2 | c.516C>G p.G172= | Silent (SNP) | VAF 41/120 reads (34%) | called by muse, mutect2, varscan2
- BRCA2 | c.10107T>C p.T3369= | Silent (SNP) | VAF 108/298 reads (36%) | called by muse, mutect2, varscan2
- CATSPER1 | c.2283C>T p.A761= | Silent (SNP) | VAF 43/162 reads (27%) | catalogued as rs534081949; called by muse, mutect2, varscan2
- CBLIF | c.1131G>T p.A377= | Silent (SNP) | VAF 120/432 reads (28%) | called by muse, mutect2, varscan2
- CFAP54 | c.4023A>G p.Q1341= | Silent (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2
- COIL | c.1254A>G p.G418= | Silent (SNP) | VAF 49/208 reads (24%) | called by muse, mutect2, varscan2
- CSNK1A1 | c.930C>G p.A310= | Silent (SNP) | VAF 18/227 reads (8%) | catalogued as COSV55797212; called by muse, mutect2
- DOCK3 | c.5052C>T p.L1684= | Silent (SNP) | VAF 51/109 reads (47%) | catalogued as rs752908267; called by muse, mutect2, varscan2
- DYNC1H1 | c.1179C>T p.L393= | Silent (SNP) | VAF 130/240 reads (54%) | called by muse, mutect2, varscan2
- ELOA | c.957G>C p.P319= | Silent (SNP) | VAF 51/254 reads (20%) | called by muse, mutect2, varscan2
- FBLL1 | c.861C>A p.A287= | Silent (SNP) | VAF 75/185 reads (41%) | called by muse, mutect2, varscan2
- FBXL6 | c.1218A>T p.P406= | Silent (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- FRAS1 | c.11868G>A p.K3956= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as COSV99354929; called by muse, mutect2, varscan2
- GMIP | c.2793C>G p.P931= | Silent (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- GPAA1 | c.1668G>T p.T556= | Silent (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- GPR26 | c.369G>C p.A123= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV52933137; called by muse, mutect2, varscan2
- GTF3C4 | c.2008C>T p.L670= | Silent (SNP) | VAF 78/168 reads (46%) | called by muse, mutect2, varscan2
- H2AC6 | c.147G>T p.P49= | Silent (SNP) | VAF 32/76 reads (42%) | called by muse, mutect2, varscan2
- HS3ST5 | c.315C>A p.A105= | Silent (SNP) | VAF 98/277 reads (35%) | catalogued as COSV57146998; called by muse, mutect2, varscan2
- HSD3B1 | c.960C>A p.V320= | Silent (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
- KLHL4 | c.732C>A p.V244= | Silent (SNP) | VAF 34/58 reads (59%) | called by muse, mutect2, varscan2
- LILRB2 | c.531C>T p.S177= | Silent (SNP) | VAF 38/135 reads (28%) | called by muse, mutect2, varscan2
- LILRB5 | c.684C>A p.I228= | Silent (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2
- LOXHD1 | c.4656C>T p.N1552= | Silent (SNP) | VAF 84/309 reads (27%) | catalogued as rs762118454, COSV56074281; called by muse, mutect2, varscan2
- MMP9 | c.915C>T p.D305= | Silent (SNP) | VAF 30/161 reads (19%) | called by muse, mutect2, varscan2
- MORC1 | c.888A>G p.V296= | Silent (SNP) | VAF 30/130 reads (23%) | catalogued as rs1284032286; called by muse, mutect2, varscan2
- MUC16 | c.11628C>T p.T3876= | Silent (SNP) | VAF 28/96 reads (29%) | called by muse, mutect2, varscan2
- MYBPC2 | c.1647C>A p.T549= | Silent (SNP) | VAF 44/142 reads (31%) | called by muse, mutect2, varscan2
- MYH3 | c.3987C>T p.A1329= | Silent (SNP) | VAF 65/247 reads (26%) | called by muse, mutect2, varscan2
- NAV2 | c.6801G>T p.L2267= (on ENST00000396087 / NM_001244963.2; = p.L2208= on NM_145117.5) | Silent (SNP) | VAF 122/448 reads (27%) | called by muse, mutect2, varscan2
- NLRP8 | c.1777C>T p.L593= | Silent (SNP) | VAF 37/159 reads (23%) | catalogued as COSV52589808; called by muse, mutect2, varscan2
- NME8 | c.681A>G p.V227= | Silent (SNP) | VAF 190/483 reads (39%) | called by muse, mutect2, varscan2
- NOTCH1 | c.2619C>T p.C873= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as rs375714105; called by muse, mutect2, varscan2
- NRXN1 | c.2991C>A p.T997= | Silent (SNP) | VAF 75/175 reads (43%) | called by muse, mutect2, varscan2
- OR2J2 | c.141C>T p.I47= | Silent (SNP) | VAF 17/182 reads (9%) | catalogued as COSV65847924; called by muse, mutect2, varscan2
- OR4D9 | c.798C>A p.P266= | Silent (SNP) | VAF 54/216 reads (25%) | called by muse, mutect2, varscan2
- OR51I1 | c.843C>T p.V281= | Silent (SNP) | VAF 81/336 reads (24%) | catalogued as rs956266746, COSV66508474; called by muse, mutect2, varscan2
- OR5T1 | c.549C>A p.S183= | Silent (SNP) | VAF 55/222 reads (25%) | catalogued as COSV100479073; called by muse, mutect2, varscan2
- OR6B2 | c.726C>A p.A242= | Silent (SNP) | VAF 37/151 reads (25%) | called by muse, mutect2, varscan2
- OR8K3 | c.549T>C p.P183= | Silent (SNP) | VAF 55/162 reads (34%) | catalogued as rs1186191273; called by muse, mutect2, varscan2
- P2RY8 | c.93G>A p.S31= | Silent (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- PAN2 | c.1083G>A p.P361= | Silent (SNP) | VAF 32/302 reads (11%) | catalogued as rs375389603; called by muse, mutect2, varscan2
- PAQR7 | c.972C>T p.G324= | Silent (SNP) | VAF 27/91 reads (30%) | called by muse, mutect2, varscan2
- POU3F4 | c.639C>A p.A213= | Silent (SNP) | VAF 101/157 reads (64%) | catalogued as COSV64538002, COSV64541445; called by muse, mutect2, varscan2
- PTPRR | c.1326A>G p.S442= | Silent (SNP) | VAF 34/135 reads (25%) | catalogued as rs759452023; called by muse, mutect2, varscan2
- PYGO2 | c.1033C>T p.L345= | Silent (SNP) | VAF 54/185 reads (29%) | catalogued as rs1368737957; called by muse, mutect2, varscan2
- SEMA5B | c.786C>T p.I262= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- SLC35F3 | c.234C>T p.S78= (on ENST00000366617 / NM_001300845.1; = p.S147= on NM_173508.4) | Silent (SNP) | VAF 71/223 reads (32%) | called by muse, mutect2, varscan2
- SPG11 | c.1371C>G p.T457= | Silent (SNP) | VAF 38/97 reads (39%) | called by muse, mutect2, varscan2
- SYNE1 | c.4704G>T p.V1568= (on ENST00000367255 / NM_182961.4; = p.V1575= on NM_033071.3) | Silent (SNP) | VAF 81/296 reads (27%) | called by muse, varscan2
- TAF1L | c.5052T>C p.F1684= | Silent (SNP) | VAF 49/453 reads (11%) | called by muse, mutect2, varscan2
- TMEM132C | c.492G>T p.G164= | Silent (SNP) | VAF 80/292 reads (27%) | catalogued as COSV70656884; called by muse, mutect2
- TNXB | c.4975C>A p.R1659= (on ENST00000647633; = p.R1412= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as rs761371066; called by muse, mutect2, varscan2
- TPTE | c.1570C>A p.R524= (on ENST00000618007 / NM_199261.4; = p.R506= on NM_199259.4) | Silent (SNP) | VAF 155/726 reads (21%) | catalogued as rs537829038; called by muse, mutect2, varscan2
- UBE4B | c.1776G>C p.G592= (on ENST00000343090 / NM_001105562.3; = p.G463= on NM_006048.5) | Silent (SNP) | VAF 52/184 reads (28%) | called by muse, mutect2, varscan2
- VCX3B | c.303C>T p.H101= | Silent (SNP) | VAF 4/6 reads (67%) | catalogued as rs376239387, COSV66842912; called by mutect2, varscan2
- ZNF513 | c.1437T>C p.Y479= | Silent (SNP) | VAF 89/375 reads (24%) | called by muse, mutect2, varscan2
- ZNF732 | c.567T>C p.H189= | Silent (SNP) | VAF 54/176 reads (31%) | called by muse, mutect2, varscan2
- AC068587.4 | n.683+5065G>T | Intron (SNP) | VAF 42/401 reads (10%) | catalogued as rs1353275658; called by muse, varscan2
- AC139769.1 | n.214-4320A>C | Intron (SNP) | VAF 27/112 reads (24%) | called by muse, mutect2, varscan2
- AL139327.1 | n.237C>A | RNA (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- ALDH1A2 | c.-4C>G | 5'UTR (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- ATP2A3 | c.3068+258G>T | Intron (SNP) | VAF 52/205 reads (25%) | catalogued as rs764329508; called by muse, mutect2, varscan2
- BMP1 | c.2108-30C>G | Intron (SNP) | VAF 40/132 reads (30%) | called by muse, mutect2, varscan2
- C9orf85 | c.323+1199C>A | Intron (SNP) | VAF 54/142 reads (38%) | called by muse, mutect2, varscan2
- CRHBP | c.82-60G>T | Intron (SNP) | VAF 48/130 reads (37%) | called by muse, mutect2, varscan2
- DCHS2 | n.7967T>C | RNA (SNP) | VAF 55/166 reads (33%) | catalogued as rs374185470; called by muse, mutect2, varscan2
- DCHS2 | n.2326C>G | RNA (SNP) | VAF 47/211 reads (22%) | called by muse, mutect2, varscan2
- DLC1 | c.1348+90576del | Intron (DEL) | VAF 64/269 reads (24%) | called by mutect2, pindel, varscan2
- FAM166A | c.653-165G>A | Intron (SNP) | VAF 31/128 reads (24%) | called by muse, mutect2, varscan2
- GRIN2B | c.1654+11G>A | Intron (SNP) | VAF 107/321 reads (33%) | called by muse, varscan2
- HCRTR2 | c.-27T>C | 5'UTR (SNP) | VAF 34/224 reads (15%) | catalogued as rs200342715; called by muse, mutect2, varscan2
- HERC2 | c.13273-264G>T | Intron (SNP) | VAF 52/297 reads (18%) | catalogued as COSV55309288; called by muse, mutect2, varscan2
- HES6 | chr2:238240639 C>T | 5'Flank (SNP) | VAF 7/16 reads (44%) | catalogued as rs1559316807; called by muse, mutect2, varscan2
- IQUB | c.1023+24G>T | Intron (SNP) | VAF 73/162 reads (45%) | called by muse, mutect2, varscan2
- JAZF1 | c.116-13G>T | Intron (SNP) | VAF 25/195 reads (13%) | called by muse, mutect2, varscan2
- LIG1 | c.1933-33T>A | Intron (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2
- MKRN9P | n.634A>T | RNA (SNP) | VAF 81/287 reads (28%) | called by muse, mutect2, varscan2
- MUC19 | n.5973C>T | RNA (SNP) | VAF 116/418 reads (28%) | called by muse, mutect2, varscan2
- NAP1L6P | n.515A>T | RNA (SNP) | VAF 24/36 reads (67%) | called by muse, mutect2, varscan2
- OR52N2 | c.-1C>G | 5'UTR (SNP) | VAF 49/137 reads (36%) | catalogued as rs763518119; called by muse, mutect2, varscan2
- PAX6 | c.523+46C>T | Intron (SNP) | VAF 54/206 reads (26%) | catalogued as rs1355725292; called by muse, mutect2, varscan2
- PCM1 | c.783+228G>T | Intron (SNP) | VAF 66/294 reads (22%) | called by muse, mutect2, varscan2
- RBM39 | c.1226-705G>C | Intron (SNP) | VAF 61/208 reads (29%) | called by muse, varscan2
- RNF217-AS1 | n.1892C>T | RNA (SNP) | VAF 48/109 reads (44%) | catalogued as rs963071245; called by muse, mutect2, varscan2
- RYR3 | c.13626-66C>G | Intron (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- SCML2P1 | chr18:6928460 G>T | 3'Flank (SNP) | VAF 33/133 reads (25%) | called by muse, mutect2, varscan2
- SETBP1 | c.540+7367G>T | Intron (SNP) | VAF 43/157 reads (27%) | catalogued as COSV56341584; called by muse, mutect2, varscan2
- SIM2 | c.258+22A>G | Intron (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- SLC9B1P1 | n.465C>A | RNA (SNP) | VAF 18/178 reads (10%) | called by muse, mutect2
- SNORD116-19 | n.12G>T | RNA (SNP) | VAF 88/360 reads (24%) | called by muse, mutect2, varscan2
- SYNE1 | c.3027+27G>T | Intron (SNP) | VAF 54/177 reads (31%) | called by muse, mutect2, varscan2
- TACC2 | c.5573+39C>T | Intron (SNP) | VAF 148/319 reads (46%) | catalogued as rs753377264; called by mutect2, varscan2
- TBX3 | c.717+34G>C | Intron (SNP) | VAF 30/96 reads (31%) | called by muse, mutect2, varscan2
- TENT4B | chr16:50152936 G>C | 5'Flank (SNP) | VAF 10/20 reads (50%) | called by muse, varscan2
- TMEM63A | c.746+12G>T | Intron (SNP) | VAF 43/157 reads (27%) | called by muse, mutect2, varscan2
- TTC14 | c.1290+33A>G | Intron (SNP) | VAF 43/154 reads (28%) | called by muse, mutect2, varscan2
- TTN | c.10361-5510C>A | Intron (SNP) | VAF 92/384 reads (24%) | called by muse, mutect2, varscan2
- UBE2DNL | n.131C>A | RNA (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- Unknown | chr8:74752514 C>T | IGR (SNP) | VAF 83/270 reads (31%) | called by muse, mutect2, varscan2
- WSCD1 | c.-12C>A | 5'UTR (SNP) | VAF 23/67 reads (34%) | catalogued as COSV58498172; called by muse, mutect2, varscan2
- ZFAT | c.2475+20G>A | Intron (SNP) | VAF 89/223 reads (40%) | catalogued as rs766431939; called by muse, mutect2, varscan2
- ZNF134 | c.-107G>T | 5'UTR (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- ZNF875 | c.-106G>A | 5'UTR (SNP) | VAF 11/101 reads (11%) | called by muse, mutect2, varscan2
- ZSWIM4 | chr19:13836350 G>A | 3'Flank (SNP) | VAF 14/133 reads (11%) | called by muse, mutect2
